Somatic mutation profile of tumor specimen TCGA-CC-A5UC-01A (aliquot TCGA-CC-A5UC-01A-11D-A28X-10) from TCGA case TCGA-CC-A5UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.4 years (23,156 days).
Specimen TCGA-CC-A5UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0473920-3dbc-4cb0-b570-590bed1b4c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A5UC-10A (Blood Derived Normal), aliquot TCGA-CC-A5UC-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7f6eaff-16df-420a-bff5-4a3a2aee05a0

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.3146G>A p.G1049D (on ENST00000326724 / NM_001080395.3; = p.G946D on NM_004920.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58368350; called by muse, mutect2, varscan2
- ACSF3 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs754435301, COSV58079051; called by muse, mutect2, varscan2
- ALDH1B1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV66620068, COSV66620698; called by muse, mutect2, varscan2
- ANKRD34B | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as rs772456899, COSV58614097; called by muse, mutect2, varscan2
- ATOH1 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60038162; called by muse, mutect2, varscan2
- ATP1A2 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150784486, COSV63404287; called by muse, varscan2
- CACNA1E | c.6431C>T p.P2144L (on ENST00000367573 / NM_001205293.3; = p.P2101L on NM_000721.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.701); catalogued as rs1350235743, COSV62401324; called by muse, mutect2, varscan2
- CFAP44 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV55612453; called by muse, mutect2
- COL13A1 | c.1865G>A p.G622D (on ENST00000398978 / NM_001130103.2; = p.G550D on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62571197; called by muse, mutect2, varscan2
- CST8 | c.41T>A p.I14N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV55671413; called by muse, mutect2, varscan2
- DNAH7 | c.4896+1G>T p.X1632_splice | Splice Site (SNP) | VAF 42/187 reads (22%) | catalogued as COSV56769892; called by muse, mutect2, varscan2
- DNAH8 | c.10311+2T>C p.X3437_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV59455323; called by muse, mutect2, varscan2
- DNAJB8 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142768827; called by muse, mutect2, varscan2
- DST | c.17009T>G p.L5670R (on ENST00000361203 / NM_001374722.1; = p.L3367R on NM_015548.5) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55021482; called by muse, mutect2, varscan2
- DZIP3 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | catalogued as COSV64312518; called by muse, mutect2
- EDN1 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 108/361 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV65080898; called by muse, mutect2, varscan2
- EPHA5 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56651385; called by muse, mutect2, varscan2
- ERBB3 | c.340A>T p.K114* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as COSV57256126; called by muse, mutect2, varscan2
- GRM6 | c.1449C>A p.S483R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51444036; called by muse, mutect2, varscan2
- KIRREL1 | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1299247868, COSV63288169; called by muse, mutect2, varscan2
- LILRB5 | c.1545C>A p.S515R (on ENST00000449561 / NM_001081442.3; = p.S514R on NM_006840.5) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV60258460; called by muse, mutect2, varscan2
- LONRF3 | c.1672A>G p.I558V (on ENST00000371628 / NM_001031855.3; = p.I517V on NM_024778.5) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV59153414; called by muse, mutect2, varscan2
- LRFN2 | c.1612A>G p.I538V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV57828897; called by muse, mutect2, varscan2
- MRPL3 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs764942168, COSV53914432, COSV53914960; called by muse, mutect2, varscan2
- MTOR | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as COSV63873099; called by muse, mutect2, varscan2
- MUC5B | c.4813G>A p.G1605R | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV71593068; called by muse, mutect2, varscan2
- OR2T2 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 58/958 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737548, COSV61618333; called by muse, mutect2
- PCK1 | c.484del p.D162Ifs*12 | Frame Shift Del (DEL) | VAF 25/137 reads (18%) | catalogued as COSV100100688; called by mutect2, pindel, varscan2
- PDZRN4 | c.2338C>G p.Q780E (on ENST00000402685 / NM_001164595.2; = p.Q522E on NM_013377.4) | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV54205312, COSV54210064; called by muse, mutect2, varscan2
- PLA2G4E | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV68150696; called by muse, mutect2
- PLB1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59828249; called by mutect2, varscan2
- PPP1CA | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as COSV57237247; called by muse, mutect2
- PRAMEF19 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1413261638; called by muse, mutect2, varscan2
- RABGGTA | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52863717, COSV52864080; called by muse, mutect2, varscan2
- REEP2 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54735236; called by mutect2, varscan2
- RHPN2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as rs1396509245, COSV54280508; called by muse, mutect2, varscan2
- SERTAD4 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.751); catalogued as COSV65399562; called by muse, mutect2, varscan2
- SLC25A38 | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56194723; called by muse, mutect2, varscan2
- TDRD1 | c.3410T>C p.M1137T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52591964; called by muse, mutect2, varscan2
- UBQLN2 | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57739818; called by muse, mutect2, varscan2
- ZFC3H1 | c.4025A>T p.N1342I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV66433645; called by muse, mutect2, varscan2
- ZNF267 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as rs762477768, COSV56251190; called by muse, mutect2, varscan2
- ZNF551 | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs1449050414, COSV56593447; called by muse, mutect2, varscan2
- AXIN1 | c.674del p.S225Tfs*17 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel*, varscan2
- IGHV3-21 | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RPS29 | c.-15_9del | Translation Start Site (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- ADCY9 | c.2502C>T p.S834= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1163256044, COSV53576906; called by muse, mutect2, varscan2
- ALPG | c.460C>A p.R154= | Silent (SNP) | VAF 54/255 reads (21%) | catalogued as COSV54966589; called by muse, mutect2, varscan2
- DISP1 | c.1833C>A p.T611= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV52660617; called by muse, mutect2
- GRAMD1B | c.1513C>A p.R505= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV59206202; called by muse, mutect2, varscan2
- HMCN1 | c.5679T>C p.A1893= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV54909601; called by muse, mutect2, varscan2
- MBD5 | c.498T>C p.N166= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV68697927; called by muse, mutect2
- MGA | c.8862C>A p.L2954= (on ENST00000219905 / NM_001164273.1; = p.L2745= on NM_001080541.2) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV54956394; called by muse, mutect2, varscan2
- PKD1L1 | c.5031T>G p.A1677= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as COSV56968295; called by muse, mutect2, varscan2
- PLEKHM2 | c.2988C>T p.S996= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as rs1428876693, COSV53817382; called by muse, mutect2, varscan2
- PNPLA3 | c.684C>T p.P228= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV53378966; called by muse, mutect2, varscan2
- PTBP2 | c.918A>G p.T306= (on ENST00000426398 / NM_001300986.2; = p.T298= on NM_021190.4) | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV64624976; called by muse, mutect2, varscan2
- SUSD1 | c.267A>T p.T89= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV62584216; called by muse, mutect2, varscan2
- SVEP1 | c.10545G>A p.V3515= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV52840400; called by muse, mutect2, varscan2
- TRIM36 | c.2079G>A p.V693= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV56690886; called by muse, mutect2, varscan2
- ZNF208 | c.1824C>A p.P608= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV68108109; called by muse, mutect2
- TRPM3 | c.979+16613G>T | Intron (SNP) | VAF 26/130 reads (20%) | catalogued as COSV62469962, COSV62471479; called by muse, mutect2, varscan2
